Somatic mutation profile of tumor specimen TCGA-24-2289-01A (aliquot TCGA-24-2289-01A-01W-0799-08) from TCGA case TCGA-24-2289, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.0 years (25,191 days).
Specimen TCGA-24-2289-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9979dfde-ded4-4922-9267-9baa5bfff6d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2289-10A (Blood Derived Normal), aliquot TCGA-24-2289-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e91fe517-b079-41ab-913d-4ff15f0ab685

The open-access MAF lists 182 somatic variants for this specimen: 148 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 33, Nonsense Mutation 12, Frame Shift Del 5, In Frame Del 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 87/178 reads (49%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1028G>T p.C343F | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59374994; called by muse, mutect2, varscan2
- ADAR | c.3116A>G p.K1039R | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs888096276, CM060799, CM103143, COSV52721166; called by muse, mutect2, varscan2
- ADGRF5 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 74/355 reads (21%) | catalogued as COSV51940398; called by muse, mutect2, varscan2
- AKR1C1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as COSV66499965; called by muse, mutect2, varscan2
- ANK2 | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 181/310 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV52189101; called by muse, mutect2, varscan2
- APOB | c.8869T>A p.F2957I | Missense Mutation (SNP) | VAF 75/688 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV51952683; called by muse, mutect2, varscan2
- ARHGEF10 | c.415G>A p.E139K (on ENST00000398564; = p.E115K on NM_014629.4) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV50678552; called by muse, mutect2, varscan2
- ATRNL1 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV61817366; called by muse, mutect2, varscan2
- B3GNT4 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57337523; called by muse, mutect2, varscan2
- BBX | c.1313T>C p.I438T | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs79840732, COSV57895038; called by muse, mutect2, varscan2
- BCLAF1 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as rs750163942, COSV99219216; called by muse, mutect2
- BTRC | c.1541T>A p.F514Y (on ENST00000370187 / NM_033637.4; = p.F478Y on NM_003939.5) | Missense Mutation (SNP) | VAF 171/383 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64581035; called by muse, mutect2, varscan2
- C10orf71 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs779754617, COSV60513406; called by muse, mutect2, varscan2
- C3orf70 | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs748785029, COSV58590657; called by muse, mutect2, varscan2
- CACNA1F | c.4510G>T p.A1504S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59907068; called by muse, mutect2
- CACNA1S | c.1517G>T p.S506I | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV62943757; called by muse, mutect2, varscan2
- CASQ1 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 97/358 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV63624561; called by muse, mutect2, varscan2
- CCL27 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52405748; called by muse, mutect2, varscan2
- CCT3 | c.994G>C p.V332L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV55291543; called by muse, mutect2, varscan2
- CDC27 | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.469); catalogued as COSV50381530; called by muse, mutect2, varscan2
- CFAP251 | c.1298G>C p.S433T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56616044; called by muse, mutect2, varscan2
- CMTM4 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.089); catalogued as COSV58063666, COSV58063744; called by muse, mutect2, varscan2
- CNTRL | c.4988T>C p.I1663T | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53053659; called by muse, mutect2, varscan2
- COL22A1 | c.1462G>T p.V488F | Missense Mutation (SNP) | VAF 148/1350 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100275488; called by muse, mutect2, varscan2
- COL9A1 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs753682260, COSV100294120, COSV57893257; called by muse, mutect2, varscan2
- CSMD3 | c.6400A>C p.S2134R (on ENST00000297405 / NM_001363185.1; = p.S2030R on NM_052900.3) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs200280408, COSV52240147; called by muse, mutect2
- DARS2 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV53409139; called by muse, mutect2, varscan2
- DEPTOR | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 126/676 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV53822190; called by muse, mutect2, varscan2
- DIAPH2 | c.2089G>T p.G697W | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs1242890165, COSV61292604; called by muse, mutect2, varscan2
- DIP2A | c.3402A>C p.K1134N | Missense Mutation (SNP) | VAF 130/215 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV59486953; called by muse, mutect2, varscan2
- DLGAP5 | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV55963899, COSV55965409; called by muse, mutect2, varscan2
- DNAH11 | c.6612C>A p.N2204K | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60981905; called by muse, mutect2, varscan2
- DST | c.2722G>T p.D908Y (on ENST00000361203 / NM_001374722.1; = p.D582Y on NM_001723.6) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99749333; called by muse, mutect2
- EGFR | c.2147A>G p.K716R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.283); catalogued as COSV51801941; called by muse, mutect2, varscan2
- EIF4B | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs746524556, COSV50409106; called by muse, mutect2, varscan2
- FAM161A | c.1176A>T p.L392F | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100281166, COSV56768738; called by muse, mutect2, varscan2
- FAM222A | c.1182G>C p.K394N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV62724046; called by muse, mutect2
- FBXL20 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 114/491 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52904530; called by muse, mutect2, varscan2
- FERMT2 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV58409453; called by muse, mutect2, varscan2
- FGFR4 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as rs1196666686, COSV52811176; called by muse, mutect2, varscan2
- FLACC1 | c.374A>T p.N125I | Missense Mutation (SNP) | VAF 136/584 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs979332847, COSV53787539; called by muse, mutect2, varscan2
- FRYL | c.4033G>C p.V1345L | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV51962671; called by muse, varscan2
- GPR101 | c.912G>C p.E304D | Missense Mutation (SNP) | VAF 202/888 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53240266, COSV99981198; called by muse, mutect2, varscan2
- GPR137C | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58707089; called by muse, mutect2, varscan2
- HEPH | c.2243C>A p.P748H (on ENST00000343002; = p.P481H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57972427; called by muse, mutect2, varscan2
- HERC1 | c.9453_9479del p.S3152_Q3160del | In Frame Del (DEL) | VAF 45/123 reads (37%) | catalogued as COSV71250300; called by mutect2, pindel, varscan2
- HUWE1 | c.7029G>T p.Q2343H | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV53364077; called by muse, mutect2, varscan2
- IMMP2L | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100065893; called by muse, mutect2, varscan2
- INPP5F | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62823836; called by muse, mutect2, varscan2
- ITGA10 | c.1670C>A p.P557H | Missense Mutation (SNP) | VAF 28/605 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100994615; called by muse, mutect2
- KALRN | c.7489C>T p.R2497W (on ENST00000360013 / NM_001024660.4; = p.R800W on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774067123, COSV52265116; called by muse, mutect2
- KBTBD4 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV100442794; called by muse, mutect2, varscan2
- KIF17 | c.1161G>C p.Q387H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV56122561; called by muse, mutect2, varscan2
- KLB | c.2624G>A p.W875* | Nonsense Mutation (SNP) | VAF 24/123 reads (20%) | catalogued as COSV99961863; called by muse, mutect2, varscan2
- KLHL38 | c.845A>C p.Y282S | Missense Mutation (SNP) | VAF 73/1644 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100384198; called by muse, mutect2
- LIAS | c.355G>T p.A119S (on ENST00000261434 / NM_001363700.2; = p.A222S on NM_006859.4) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV54697332; called by muse, mutect2, varscan2
- LMBRD2 | c.1484T>G p.L495W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99682470; called by muse, mutect2
- LRP1B | c.6896A>T p.D2299V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV67275742; called by muse, mutect2, varscan2
- MAN2A2 | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64639948; called by muse, mutect2, varscan2
- MAP2 | c.4427T>C p.V1476A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV52308236; called by muse, mutect2, varscan2
- MAP3K21 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 44/120 reads (37%) | catalogued as COSV64041616; called by muse, mutect2, varscan2
- MCM3AP | c.3064C>A p.P1022T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99386308; called by muse, mutect2
- MED13L | c.4948C>A p.Q1650K | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV99927513; called by muse, mutect2, varscan2
- MEFV | c.935G>T p.S312I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV54827687; called by muse, mutect2, varscan2
- MMRN1 | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs139015467, COSV53342821; called by muse, mutect2, varscan2
- MUC5B | c.14444C>T p.T4815M | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs199943848; called by muse, mutect2
- MXRA5 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.672); catalogued as rs763948182, COSV54229068, COSV54250951; called by muse, mutect2, varscan2
- MYH13 | c.4130C>A p.T1377N | Missense Mutation (SNP) | VAF 168/562 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV52843106; called by muse, mutect2, varscan2
- MYO16 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 173/306 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs762038297, COSV51781761; called by muse, mutect2, varscan2
- NDRG4 | c.236A>T p.Q79L (on ENST00000570248 / NM_001378344.1; = p.Q111L on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.446); catalogued as COSV50751873; called by muse, mutect2, varscan2
- NDUFB11 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.136); catalogued as COSV52102905; called by muse, mutect2, varscan2
- NMU | c.125T>A p.L42* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as COSV51702279; called by muse, mutect2, varscan2
- NOTCH3 | c.5111T>G p.M1704R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV54650816; called by muse, mutect2
- NPAP1 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.192); catalogued as COSV61511412; called by muse, mutect2
- NPHP4 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.525); catalogued as COSV65394144; called by muse, mutect2, varscan2
- NPHS1 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62289915; called by muse, mutect2, varscan2
- NUMA1 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs548451727, COSV61187594; called by muse, mutect2, varscan2
- OPHN1 | c.260T>C p.F87S | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62787036; called by muse, mutect2, varscan2
- OR2C3 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs376920492, COSV100825565; called by mutect2, varscan2
- OR4S2 | c.69A>T p.K23N | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV56748412; called by muse, mutect2, varscan2
- OR5B3 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 106/497 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV58678679; called by muse, mutect2, varscan2
- OR8K1 | c.400A>T p.K134* | Nonsense Mutation (SNP) | VAF 106/544 reads (19%) | catalogued as COSV99686993; called by muse, mutect2
- OSBP | c.1474A>G p.S492G | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55665810; called by muse, mutect2, varscan2
- PADI6 | c.2047G>C p.V683L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV61885800; called by muse, mutect2, varscan2
- PAPLN | c.1025T>A p.M342K (on ENST00000554301; = p.M315K on NM_173462.4) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53724029; called by muse, mutect2, varscan2
- PARP10 | c.1541G>C p.C514S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57300157; called by muse, mutect2, varscan2
- PDE6A | c.1098C>G p.D366E | Missense Mutation (SNP) | VAF 155/759 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54931423; called by muse, mutect2, varscan2
- PHF8 | c.1840A>G p.T614A (on ENST00000357988 / NM_001184896.1; = p.T578A on NM_015107.3) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV57687992; called by muse, mutect2, varscan2
- PHLDB1 | c.817A>T p.S273C | Missense Mutation (SNP) | VAF 124/376 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV61881910; called by muse, mutect2, varscan2
- PKP1 | c.950G>T p.R317M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV55825459; called by muse, mutect2, varscan2
- PLEKHO1 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 138/373 reads (37%) | catalogued as COSV99215033; called by muse, mutect2, varscan2
- PLXNA4 | c.5299A>G p.T1767A | Missense Mutation (SNP) | VAF 79/482 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58160655; called by muse, mutect2, varscan2
- POF1B | c.871T>G p.S291A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV53140714; called by muse, mutect2, varscan2
- PRKD3 | c.920T>C p.F307S | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52218658; called by muse, mutect2, varscan2
- PSMC5 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56742149; called by muse, mutect2, varscan2
- PTPN13 | c.4567C>G p.P1523A (on ENST00000411767 / NM_080683.3; = p.P1504A on NM_006264.3) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV100363816; called by muse, mutect2
- PXN | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV57221925; called by muse, mutect2, varscan2
- RAD21 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755363046, COSV52064177; called by muse, mutect2
- RBM22 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 36/174 reads (21%) | catalogued as COSV52273195; called by muse, mutect2, varscan2
- RP1 | c.6231G>T p.Q2077H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55109791, COSV55127108; called by muse, mutect2, varscan2
- SBF2 | c.2297A>C p.N766T | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56311645; called by muse, mutect2
- SCGB3A2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 188/886 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as COSV57023846; called by muse, mutect2, varscan2
- SCN4B | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV61253007; called by muse, mutect2, varscan2
- SEL1L3 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs190624648, COSV53548506; called by muse, mutect2, varscan2
- SIGLEC10 | c.1642T>G p.F548V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV59486713; called by muse, mutect2, varscan2
- SLC39A7 | c.1111G>T p.V371F | Missense Mutation (SNP) | VAF 14/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100761696, COSV63002871; called by muse, mutect2
- SLC4A11 | c.1097T>G p.I366S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV101195861; called by muse, mutect2, varscan2
- SNCAIP | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV54407001; called by muse, mutect2, varscan2
- SNRPD1 | c.32G>C p.S11T | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV100303309; called by muse, mutect2
- SPTBN1 | c.5944C>A p.H1982N | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.324); catalogued as COSV100441437; called by muse, mutect2
- SPTBN2 | c.4882A>G p.K1628E | Missense Mutation (SNP) | VAF 119/248 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100017907; called by mutect2, varscan2
- SVIL | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV63448330; called by muse, mutect2, varscan2
- TBC1D5 | c.2382C>A p.D794E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV53771194; called by muse, varscan2
- TECTB | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65596555; called by mutect2, varscan2
- TIMMDC1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 191/445 reads (43%) | catalogued as COSV99956025; called by muse, mutect2, varscan2
- TLN2 | c.1942G>T p.G648* | Nonsense Mutation (SNP) | VAF 10/228 reads (4%) | catalogued as COSV60893214; called by muse, mutect2
- TMEM248 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1480722523, COSV58578505; called by muse, mutect2, varscan2
- TMEM74 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1237362981, COSV99865218; called by muse, mutect2, varscan2
- TMEM87B | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 256/406 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV51718661; called by muse, mutect2, varscan2
- TNFRSF10A | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1453147544, COSV55327187; called by muse, mutect2, varscan2
- TRIM58 | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 281/1681 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as COSV63572304; called by muse, mutect2, varscan2
- TRPC6 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV60261147; called by muse, mutect2, varscan2
- USF3 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV57077514; called by muse, mutect2, varscan2
- USP18 | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs533388580, COSV53174522; called by muse, mutect2, varscan2
- USP4 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55540623; called by muse, mutect2, varscan2
- WDHD1 | c.1999C>T p.H667Y | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); catalogued as rs1030585407, COSV62215744; called by muse, mutect2, varscan2
- WDR6 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58247496; called by muse, mutect2, varscan2
- ZBTB33 | c.620C>A p.T207N | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58535181; called by muse, mutect2, varscan2
- ZMAT1 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as rs141908807, COSV65658722; called by muse, varscan2
- ZNF227 | c.1097A>C p.N366T | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV57313729; called by muse, mutect2, varscan2
- ZNF438 | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 220/770 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV59200949; called by muse, varscan2
- ZNF521 | c.2967C>A p.N989K | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV64132012; called by muse, mutect2, varscan2
- ZNF567 | c.940T>G p.C314G (on ENST00000536254 / NM_001322913.1; = p.C283G on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62446564; called by muse, mutect2, varscan2
- ZNF597 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 39/196 reads (20%) | catalogued as rs755317229, COSV57085747; called by muse, mutect2, varscan2
- ZXDA | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.511); catalogued as COSV62388888; called by muse, mutect2, varscan2
- ADCY10 | c.964_981del p.T322_I327del | In Frame Del (DEL) | VAF 124/559 reads (22%) | called by mutect2, pindel, varscan2
- DGCR8 | c.508_515del p.D170Rfs*5 | Frame Shift Del (DEL) | VAF 17/117 reads (15%) | called by mutect2, pindel, varscan2
- FGGY | c.220_223del p.D74* | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by pindel, varscan2
- FHDC1 | c.816_846del p.Y272* | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel
- IGLV3-32 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- MRC1 | c.3638A>G p.K1213R | Missense Mutation (SNP) | VAF 147/579 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- OSBP2 | c.2463_2470delinsA p.L822Pfs*5 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by pindel, varscan2*
- PKD2 | c.2607del p.M870Wfs*6 | Frame Shift Del (DEL) | VAF 40/207 reads (19%) | called by mutect2, pindel, varscan2
- PLAG1 | c.681_692del p.L228_H231del | In Frame Del (DEL) | VAF 44/331 reads (13%) | called by mutect2, pindel
- RPS6KC1 | c.2995-16_3014del p.X999_splice | Splice Site (DEL) | VAF 55/389 reads (14%) | called by mutect2, pindel
- SLC13A3 | c.542-10_551del p.X181_splice | Splice Site (DEL) | VAF 42/272 reads (15%) | called by mutect2, pindel
- TRBC2 | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ADAM2 | c.90G>A p.P30= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs369551334; called by muse, mutect2, varscan2
- ANGPTL5 | c.972C>T p.C324= | Silent (SNP) | VAF 255/1022 reads (25%) | catalogued as COSV57533879; called by muse, mutect2, varscan2
- ARFGAP2 | c.1452G>C p.L484= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV53570968; called by muse, mutect2, varscan2
- BCLAF1 | c.2016G>A p.E672= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs1206324870, COSV99219215; called by muse, mutect2
- CHI3L1 | c.744G>T p.G248= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV55140223; called by muse, mutect2, varscan2
- EED | c.33G>A p.A11= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs779476263, COSV54558387, COSV54558538; called by mutect2, varscan2
- FOLH1 | c.1701T>C p.D567= | Silent (SNP) | VAF 37/186 reads (20%) | catalogued as rs756390079, COSV99922499; called by muse, mutect2, varscan2
- FZD2 | c.1515G>C p.P505= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs755824483, COSV59527949, COSV59529884, COSV59530282; called by muse, mutect2, varscan2
- HMGCL | c.841C>T p.L281= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV52527451; called by muse, mutect2, varscan2
- INSRR | c.1353A>G p.E451= | Silent (SNP) | VAF 30/215 reads (14%) | catalogued as COSV63877370; called by muse, mutect2, varscan2
- IRX1 | c.369C>T p.F123= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV57362498, COSV57363137; called by muse, mutect2, varscan2
- KDM6B | c.3828C>T p.T1276= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV54687201; called by muse, mutect2, varscan2
- MAGEA3 | c.222C>T p.T74= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100938976; called by muse, mutect2, varscan2
- MAN2A1 | c.954T>C p.V318= | Silent (SNP) | VAF 81/264 reads (31%) | catalogued as COSV54858654; called by muse, mutect2, varscan2
- MGA | c.3684C>G p.V1228= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1478256028, COSV54963131; called by muse, mutect2, varscan2
- NCAM1 | c.2064C>T p.N688= (on ENST00000316851 / NM_181351.5; = p.N678= on NM_000615.7) | Silent (SNP) | VAF 97/353 reads (27%) | catalogued as COSV57517490, COSV57524923; called by muse, mutect2, varscan2
- OCA2 | c.837T>C p.N279= | Silent (SNP) | VAF 114/331 reads (34%) | catalogued as COSV62358292; called by muse, mutect2, varscan2
- OR10W1 | c.165C>T p.G55= | Silent (SNP) | VAF 93/434 reads (21%) | catalogued as COSV67720879; called by muse, mutect2, varscan2
- OR8K1 | c.402A>G p.K134= | Silent (SNP) | VAF 110/548 reads (20%) | catalogued as COSV54403237; called by muse, mutect2
- PPIAL4A | c.9C>T p.N3= | Silent (SNP) | VAF 45/183 reads (25%) | called by muse, mutect2, varscan2
- RAE1 | c.510T>G p.P170= | Silent (SNP) | VAF 87/353 reads (25%) | catalogued as COSV100982301; called by muse, mutect2, varscan2
- RECQL | c.1704G>C p.S568= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV53707911, COSV53711991; called by muse, mutect2, varscan2
- SENP8 | c.168T>G p.P56= | Silent (SNP) | VAF 207/536 reads (39%) | catalogued as rs748611390, COSV100566465; called by muse, mutect2, varscan2
- SMARCA1 | c.2412T>C p.I804= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV64413909; called by muse, varscan2
- SMTN | c.1449C>T p.N483= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1398982863, COSV60783152; called by muse, mutect2, varscan2
- SRSF4 | c.1434T>G p.S478= | Silent (SNP) | VAF 44/156 reads (28%) | catalogued as COSV65695776; called by muse, mutect2, varscan2
- SUN5 | c.579C>T p.Y193= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV62182587; called by muse, mutect2, varscan2
- SVIL | c.981A>C p.V327= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV63448325; called by muse, mutect2, varscan2
- TFE3 | c.729G>A p.A243= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs782613886, COSV59946222; called by muse, mutect2, varscan2
- TMEM63B | c.2061G>A p.A687= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs753384706, COSV52482480; called by muse, mutect2, varscan2
- TRIM71 | c.1512C>A p.S504= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV67472457, COSV67472692; called by muse, mutect2, varscan2
- UBR4 | c.4227G>A p.Q1409= | Silent (SNP) | VAF 62/1060 reads (6%) | catalogued as COSV100919889; called by muse, mutect2
- VRTN | c.339G>A p.L113= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV56443716; called by muse, mutect2, varscan2
- SYNJ2 | c.3744+890C>G | Intron (SNP) | VAF 167/749 reads (22%) | catalogued as COSV100839973; called by muse, mutect2, varscan2
